Somatic mutation profile of tumor specimen TCGA-AA-3979-01A (aliquot TCGA-AA-3979-01A-01W-0995-10) from TCGA case TCGA-AA-3979, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 84.2 years (30,742 days).
Specimen TCGA-AA-3979-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e48ea490-deba-4cbb-8740-3e004227cfd6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3979-10A (Blood Derived Normal), aliquot TCGA-AA-3979-10A-01W-0999-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6648ca0d-a3bf-4043-adf9-8eaae5a7dbfa

The open-access MAF lists 158 somatic variants for this specimen: 120 protein-altering or splice-affecting, 35 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 35, Nonsense Mutation 11, Frame Shift Del 5, Frame Shift Ins 3, Splice Site 2, RNA 1, Intron 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1972C>T p.R658* (on ENST00000281708 / NM_001349798.2; = p.R578* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 47/62 reads (76%) | hotspot (GDC flag); catalogued as COSV55892162, COSV55908751; called by muse, mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 81/185 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PCBP1 | c.305T>A p.L102Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57850093, COSV57850258, COSV57850830; called by muse, mutect2, varscan2
- SCN4A | c.3938C>T p.T1313M | Missense Mutation (SNP) | VAF 99/262 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs121908547, CM941270, COSV71127251; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 262/330 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTR1B | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56705676; called by muse, mutect2, varscan2
- AMY2A | c.654G>C p.W218C | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV70214980; called by muse, mutect2, varscan2
- APC | c.2269C>T p.Q757* | Nonsense Mutation (SNP) | VAF 24/46 reads (52%) | catalogued as CD058129, CM086469, COSV104379212, COSV57388933; called by muse, mutect2, varscan2
- APC | c.4476del p.T1493Rfs*14 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | catalogued as COSV57375363; called by mutect2, pindel, varscan2
- ATP2B3 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as rs199524794, COSV99686011; called by muse, mutect2, varscan2
- ATP4A | c.2437C>T p.L813F | Missense Mutation (SNP) | VAF 34/526 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV99383135; called by muse, mutect2
- BTF3 | c.597G>C p.E199D (on ENST00000380591 / NM_001037637.1; = p.E155D on NM_001207.4) | Missense Mutation (SNP) | VAF 80/531 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV59964794; called by muse, mutect2, varscan2
- C5 | c.3340G>C p.D1114H | Missense Mutation (SNP) | VAF 85/213 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.382); catalogued as COSV99798863; called by muse, mutect2, varscan2
- CALCOCO2 | c.1133A>G p.N378S | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV99363965; called by muse, mutect2
- CATSPERB | c.2698C>T p.H900Y | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56423760; called by muse, mutect2
- CBLL2 | c.418A>G p.R140G | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as COSV100081777; called by muse, mutect2, varscan2
- CDC23 | c.1336C>G p.L446V | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); catalogued as COSV101203167; called by muse, mutect2, varscan2
- CENPJ | c.706A>G p.I236V | Missense Mutation (SNP) | VAF 30/592 reads (5%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV67883148; called by muse, mutect2
- CFAP47 | c.1039A>G p.T347A | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT tolerated (0.27); PolyPhen benign (0.061); catalogued as COSV52892319; called by muse, mutect2, varscan2
- CFAP47 | c.1174A>C p.S392R | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.594); catalogued as COSV52886455, COSV52894132; called by muse, mutect2, varscan2
- CHRD | c.2033C>T p.A678V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs769116532, COSV99200542; called by muse, varscan2
- CMYA5 | c.10438G>T p.E3480* | Nonsense Mutation (SNP) | VAF 35/82 reads (43%) | catalogued as COSV101484406; called by muse, mutect2, varscan2
- CNBD1 | c.1187T>G p.L396R | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73072298, COSV73072404, COSV73073941; called by muse, mutect2, varscan2
- CYP11B1 | c.587C>G p.T196S | Missense Mutation (SNP) | VAF 50/242 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.136); catalogued as COSV99455775; called by muse, mutect2, varscan2
- DCHS1 | c.8125A>T p.N2709Y | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV100197788; called by muse, mutect2, varscan2
- DEFB112 | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 70/144 reads (49%) | SIFT tolerated (0.84); PolyPhen benign (0.017); catalogued as rs146242544; called by muse, mutect2, varscan2
- DNAH3 | c.7727G>A p.R2576H | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs544149586, COSV54533843; called by muse, mutect2, varscan2
- DNAH5 | c.13222C>T p.R4408C | Missense Mutation (SNP) | VAF 93/218 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150046963; called by muse, mutect2, varscan2
- DRICH1 | c.233T>A p.L78* | Nonsense Mutation (SNP) | VAF 19/94 reads (20%) | catalogued as COSV58504910; called by muse, mutect2, varscan2
- DYRK4 | c.1486G>C p.E496Q | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as COSV99158281; called by muse, mutect2, varscan2
- FAM90A1 | c.1067T>C p.V356A | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (1); PolyPhen possibly damaging (0.522); catalogued as rs149708234; called by muse, mutect2, varscan2
- FBXO30 | c.897G>C p.Q299H | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV52792475; called by muse, mutect2, varscan2
- GABRA5 | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 78/103 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1221649675, COSV100165839; called by muse, mutect2, varscan2
- GALNT17 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 60/108 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1453524973, COSV61155934; called by muse, mutect2, varscan2
- GRIA1 | c.584A>C p.K195T | Missense Mutation (SNP) | VAF 110/216 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.202); catalogued as COSV99602609; called by muse, mutect2, varscan2
- GSAP | c.457-1G>C p.X153_splice | Splice Site (SNP) | VAF 70/142 reads (49%) | catalogued as COSV99990536; called by muse, mutect2, varscan2
- HACD4 | c.242C>A p.S81* | Nonsense Mutation (SNP) | VAF 30/76 reads (39%) | catalogued as COSV72136849; called by muse, mutect2, varscan2
- HTR1A | c.581G>C p.G194A | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.441); catalogued as COSV100109304; called by muse, mutect2, varscan2
- IGSF21 | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV99246369; called by muse, mutect2, varscan2
- IGSF22 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 107/284 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV60039028, COSV60039099; called by muse, mutect2, varscan2
- IGSF9B | c.3533G>A p.R1178Q | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs1345045974, COSV58073105; called by muse, mutect2, varscan2
- IRF2 | c.323T>G p.V108G | Missense Mutation (SNP) | VAF 47/53 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66930707; called by muse, mutect2, varscan2
- IRS4 | c.1817G>A p.R606H | Missense Mutation (SNP) | VAF 79/98 reads (81%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs367909187, COSV64532547, COSV64533324; called by muse, mutect2, varscan2
- JHY | c.1110T>A p.C370* | Nonsense Mutation (SNP) | VAF 22/59 reads (37%) | catalogued as COSV99913848; called by muse, mutect2, varscan2
- KCNA4 | c.1513A>C p.T505P | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV100069306; called by muse, mutect2, varscan2
- KCNT2 | c.2897T>G p.L966R | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.418); catalogued as COSV54069295, COSV54070653, COSV54077408; called by muse, mutect2, varscan2
- KIF25 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs535182976, COSV99053271; called by muse, mutect2, varscan2
- KLK12 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.258); catalogued as rs372208750; called by muse, mutect2, varscan2
- KRT71 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 56/95 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.166); catalogued as rs778601047, COSV57288926; called by muse, mutect2, varscan2
- LAIR2 | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as rs202049649, COSV56623070; called by muse, varscan2
- LMBRD1 | c.799G>C p.E267Q (on ENST00000649011; = p.E245Q on NM_018368.4) | Missense Mutation (SNP) | VAF 298/816 reads (37%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV100992721; called by muse, mutect2, varscan2
- LRP1B | c.4490A>G p.K1497R | Missense Mutation (SNP) | VAF 151/348 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV101255116, COSV67192589; called by muse, mutect2, varscan2
- MAB21L2 | c.561G>T p.W187C | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100462460; called by muse, mutect2, varscan2
- MAGEA12 | c.105G>T p.E35D | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as COSV100757088; called by muse, mutect2, varscan2
- MMP16 | c.227T>C p.M76T | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54155176; called by muse, mutect2, varscan2
- MSR1 | c.810A>T p.L270F | Missense Mutation (SNP) | VAF 66/94 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as COSV100028228; called by muse, mutect2, varscan2
- MTDH | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 35/386 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758753771, COSV60346730; called by muse, mutect2
- MYBPC3 | c.3034C>A p.Q1012K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as CM034550, COSV99921015; called by muse, varscan2
- MYL1 | c.318G>C p.K106N | Missense Mutation (SNP) | VAF 130/253 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100498791, COSV58976822; called by muse, mutect2, varscan2
- MYO16 | c.561G>C p.L187F | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV99194740; called by muse, mutect2, varscan2
- NCBP2L | c.111A>C p.E37D | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV100966530; called by muse, mutect2
- NEK4 | c.107A>C p.K36T | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51783520; called by muse, mutect2
- NOL4 | c.17A>C p.D6A | Missense Mutation (SNP) | VAF 93/116 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99308620; called by muse, mutect2, varscan2
- NUP98 | c.3944C>G p.T1315R (on ENST00000359171 / NM_001365126.1; = p.T1298R on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.058); catalogued as COSV100263543, COSV61433579; called by muse, mutect2, varscan2
- NYAP1 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.834); catalogued as rs976301402, COSV55717758; called by muse, mutect2, varscan2
- OR13C3 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs375831267; called by muse, mutect2, varscan2
- OR4C6 | c.633C>G p.I211M | Missense Mutation (SNP) | VAF 92/153 reads (60%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.129); catalogued as COSV100051880, COSV58605245; called by muse, mutect2, varscan2
- OR52J3 | c.407C>T p.T136I | Missense Mutation (SNP) | VAF 127/236 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.236); catalogued as COSV100984953; called by muse, mutect2, varscan2
- OR5F1 | c.275T>C p.I92T | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV99558967; called by muse, mutect2, varscan2
- OR6B3 | c.752T>G p.F251C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV100097704; called by muse, mutect2, varscan2
- OR8B2 | c.253_254insG p.F85Cfs*27 | Frame Shift Ins (INS) | VAF 39/116 reads (34%) | catalogued as COSV66665530; called by mutect2, pindel, varscan2
- PARVA | c.300A>G p.V100= | Splice Region (SNP) | VAF 186/418 reads (44%) | catalogued as COSV58512530; called by muse, mutect2, varscan2
- PCDHGA7 | c.1984G>A p.V662M | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as rs774353364, COSV54029028; called by muse, mutect2, varscan2
- PCDHGA7 | c.2153G>A p.R718H | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.035); catalogued as rs559398944, COSV53944887; called by muse, mutect2, varscan2
- PCNT | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs375098069, COSV52448967; called by mutect2, varscan2
- PLCB4 | c.1726A>C p.K576Q | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV53819383; called by muse, mutect2, varscan2
- PLCH1 | c.388A>G p.I130V (on ENST00000340059 / NM_001130960.2; = p.I142V on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 123/413 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); catalogued as COSV100398373; called by muse, mutect2, varscan2
- PREX1 | c.2191G>A p.V731I | Missense Mutation (SNP) | VAF 248/421 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as rs139250516; called by muse, mutect2, varscan2
- PTAR1 | c.630G>C p.K210N | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV61209678; called by muse, mutect2, varscan2
- QSOX2 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs767414712, COSV100699838; called by muse, mutect2, varscan2
- RBP3 | c.3451G>A p.A1151T | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs782249467; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RGS13 | c.419T>A p.F140Y | Missense Mutation (SNP) | VAF 65/119 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101232279; called by muse, mutect2, varscan2
- RIMS1 | c.2704C>T p.Q902* | Nonsense Mutation (SNP) | VAF 202/477 reads (42%) | catalogued as COSV99330813; called by muse, varscan2
- RIMS2 | c.1419_1420insC p.M474Hfs*8 (on ENST00000666250 / NM_001348490.2; = p.M282Hfs*8 on NM_014677.5 and 7 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 40/142 reads (28%) | catalogued as COSV99200890; called by mutect2, pindel, varscan2
- RP1L1 | c.3802G>A p.A1268T | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as rs368855563; called by muse, mutect2, varscan2
- RRP9 | c.453T>G p.C151W | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99232795; called by muse, mutect2, varscan2
- SLC16A9 | c.1384A>T p.I462F | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101264502, COSV68099925; called by muse, mutect2, varscan2
- SLC26A7 | c.1010C>A p.S337* | Nonsense Mutation (SNP) | VAF 32/217 reads (15%) | catalogued as COSV99404478; called by muse, mutect2, varscan2
- SLC5A2 | c.1624C>T p.L542F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as rs754404838, COSV57894690; called by muse, mutect2, varscan2
- SLIT2 | c.2777C>T p.P926L | Missense Mutation (SNP) | VAF 96/234 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1185951977, COSV56596750; called by muse, mutect2, varscan2
- SLITRK1 | c.929A>T p.K310M | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV101000084; called by muse, mutect2
- SMC2 | c.792G>C p.Q264H | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as COSV99659801; called by muse, mutect2, varscan2
- SNAP91 | c.580A>T p.N194Y | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99536757; called by muse, mutect2, varscan2
- SORCS1 | c.3499G>A p.A1167T | Missense Mutation (SNP) | VAF 113/255 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99550750; called by muse, mutect2, varscan2
- SORT1 | c.1365G>T p.K455N | Missense Mutation (SNP) | VAF 181/473 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV99861180; called by muse, varscan2
- SPECC1L | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 2/9 reads (22%) | catalogued as COSV58662228; called by muse, mutect2
- SSBP3 | c.1085G>A p.R362Q (on ENST00000371320 / NM_145716.4; = p.R342Q on NM_018070.5) | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58890124; called by muse, mutect2, varscan2
- TANGO6 | c.1723G>C p.V575L | Missense Mutation (SNP) | VAF 146/180 reads (81%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV99937056; called by muse, mutect2, varscan2
- TDRD1 | c.801+2T>G p.X267_splice | Splice Site (SNP) | VAF 9/94 reads (10%) | catalogued as COSV99315241; called by muse, mutect2
- TEX13A | c.895T>A p.S299T | Missense Mutation (SNP) | VAF 266/315 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100782105; called by muse, mutect2, varscan2
- TP63 | c.1485T>G p.I495M | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99289059; called by muse, mutect2, varscan2
- TRHDE | c.2932C>A p.L978I | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99672764; called by muse, mutect2, varscan2
- TRIM2 | c.1643T>A p.I548N (on ENST00000437508; = p.I575N on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100108311; called by muse, mutect2, varscan2
- TRIM41 | c.970C>G p.L324V | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100163545; called by muse, mutect2, varscan2
- TRPM4 | c.3283C>T p.R1095* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | catalogued as COSV53269294; called by muse, mutect2, varscan2
- TSPEAR | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs367641936, COSV59954595, COSV59968215; called by muse, mutect2, varscan2
- WNT3 | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.953); catalogued as COSV99843446; called by muse, mutect2, varscan2
- ZC3H6 | c.417G>C p.E139D | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs576103507, COSV100674846; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1889C>T p.T630M | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs373307729; called by muse, mutect2, varscan2
- ZMAT3 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs1472162988, COSV60995442; called by muse, mutect2, varscan2
- ZNF599 | c.920G>T p.R307L | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV100251340, COSV61395925; called by muse, mutect2, varscan2
- ZNF714 | c.1492A>T p.K498* | Nonsense Mutation (SNP) | VAF 76/161 reads (47%) | catalogued as COSV52515732; called by muse, mutect2, varscan2
- ELF3 | c.1024del p.L342Wfs*105 | Frame Shift Del (DEL) | VAF 40/108 reads (37%) | called by mutect2, pindel, varscan2
- GJC2 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.196); called by muse, mutect2
- HOMER2 | c.820A>G p.S274G (on ENST00000304231 / NM_199330.3; = p.S263G on NM_004839.4) | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- IGHG2 | c.187T>C p.Y63H | Missense Mutation (SNP) | VAF 126/147 reads (86%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH15 | c.5120_5123del p.T1707Sfs*74 | Frame Shift Del (DEL) | VAF 43/225 reads (19%) | called by pindel, varscan2
- SOX9 | c.767_768dup p.R257Gfs*23 | Frame Shift Ins (INS) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- SPNS2 | c.1518_1527del p.M506Ifs*29 | Frame Shift Del (DEL) | VAF 32/50 reads (64%) | called by pindel, varscan2
- ZHX2 | c.2145del p.M716Wfs*31 | Frame Shift Del (DEL) | VAF 85/154 reads (55%) | called by mutect2, pindel, varscan2
- ACSM5 | c.669C>T p.D223= | Silent (SNP) | VAF 74/145 reads (51%) | catalogued as rs1166362191, COSV59375165; called by muse, mutect2, varscan2
- ADAMTSL5 | c.1254G>A p.P418= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs747541597, COSV100389257; called by muse, varscan2
- AQP1 | c.675C>T p.L225= | Silent (SNP) | VAF 119/231 reads (52%) | catalogued as COSV61268218; called by muse, mutect2, varscan2
- ARHGAP19 | c.267C>T p.G89= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as rs769370762, COSV57393225; called by muse, mutect2, varscan2
- ASB3 | c.477T>G p.A159= | Silent (SNP) | VAF 41/109 reads (38%) | catalogued as COSV55080381; called by muse, mutect2, varscan2
- ATF4 | c.441T>C p.S147= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as rs781776700, COSV57480787; called by muse, mutect2, varscan2
- B3GAT2 | c.75G>C p.V25= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV57775079; called by muse, mutect2, varscan2
- B4GALNT3 | c.1929C>T p.L643= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as rs376820641; called by muse, mutect2, varscan2
- CFAP74 | c.1923G>A p.T641= | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as rs768378538, COSV54574380; called by muse, varscan2
- COL21A1 | c.1161C>A p.T387= | Silent (SNP) | VAF 90/212 reads (42%) | catalogued as COSV55181035; called by muse, mutect2, varscan2
- CTNND2 | c.1338G>A p.P446= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as rs780920780, COSV58876426; called by muse, mutect2, varscan2
- CTSA | c.129G>A p.K43= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as COSV51945344; called by muse, mutect2, varscan2
- CUL5 | c.369C>T p.G123= | Silent (SNP) | VAF 62/139 reads (45%) | catalogued as COSV67610297; called by muse, mutect2, varscan2
- CYC1 | c.951G>C p.R317= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV59645131; called by muse, mutect2, varscan2
- EPB41L1 | c.714C>T p.S238= | Silent (SNP) | VAF 50/189 reads (26%) | catalogued as rs773802695, COSV52445338; called by muse, mutect2, varscan2
- FREM1 | c.2529C>G p.L843= | Silent (SNP) | VAF 69/135 reads (51%) | catalogued as COSV66519086, COSV66530465; called by muse, mutect2, varscan2
- GC | c.75G>A p.K25= | Silent (SNP) | VAF 33/49 reads (67%) | catalogued as rs1165076401, COSV56739904, COSV99909589; called by muse, mutect2, varscan2
- GLUD2 | c.231C>T p.G77= | Silent (SNP) | VAF 27/29 reads (93%) | catalogued as COSV60152327; called by muse, mutect2, varscan2
- GRIA4 | c.2109A>G p.V703= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV56920784; called by muse, mutect2, varscan2
- HPS3 | c.1767C>G p.A589= | Silent (SNP) | VAF 141/252 reads (56%) | catalogued as COSV56057629; called by muse, mutect2, varscan2
- LRRCC1 | c.174C>T p.I58= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs965209318, COSV64483351; called by muse, varscan2
- NYAP2 | c.1227G>A p.A409= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs760442473, COSV56003812; called by muse, mutect2, varscan2
- PCDHB1 | c.186C>T p.R62= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs782601176, COSV60633430; called by muse, mutect2, varscan2
- PLA2R1 | c.3736T>C p.L1246= | Silent (SNP) | VAF 84/191 reads (44%) | catalogued as COSV51787087; called by muse, mutect2, varscan2
- POLE2 | c.1170A>G p.R390= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99365010; called by muse, mutect2
- PRAMEF17 | c.777G>A p.L259= | Silent (SNP) | VAF 51/108 reads (47%) | called by muse, mutect2, varscan2
- SCRN1 | c.90G>T p.R30= | Silent (SNP) | VAF 53/127 reads (42%) | catalogued as COSV54134309; called by muse, mutect2, varscan2
- SDC2 | c.603G>A p.A201= | Silent (SNP) | VAF 260/347 reads (75%) | catalogued as rs770229518, COSV56227441; called by muse, mutect2, varscan2
- SLC43A1 | c.270C>T p.T90= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV53561463; called by muse, mutect2
- SPART | c.1542G>A p.K514= | Silent (SNP) | VAF 10/248 reads (4%) | catalogued as COSV62085518, COSV99050420; called by muse, mutect2
- SULF1 | c.1710A>G p.P570= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99484452; called by muse, mutect2, varscan2
- TMEM214 | c.2034C>T p.F678= | Silent (SNP) | VAF 44/121 reads (36%) | catalogued as COSV53194141; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1038C>T p.S346= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs767844378, COSV54652358; called by muse, mutect2, varscan2
- TTLL6 | c.1941T>C p.N647= (on ENST00000393382 / NM_001130918.3; = p.N340= on NM_173623.3) | Silent (SNP) | VAF 92/195 reads (47%) | catalogued as COSV64979695; called by muse, mutect2, varscan2
- VCAN | c.402C>T p.Y134= | Silent (SNP) | VAF 38/73 reads (52%) | catalogued as rs558279284, COSV54117324; called by muse, mutect2, varscan2
- DCHS2 | n.8364T>C | RNA (SNP) | VAF 20/91 reads (22%) | catalogued as COSV100602745; called by muse, mutect2, varscan2
- DGAT2L6 | c.*2A>C | 3'UTR (SNP) | VAF 37/42 reads (88%) | catalogued as COSV100284160; called by muse, mutect2, varscan2
- DPP6 | c.627+20736G>T | Intron (SNP) | VAF 11/44 reads (25%) | catalogued as COSV100128400; called by muse, mutect2, varscan2
